FM case AD3469 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach.
https://portal.gdc.cancer.gov/cases/7d07c6a9-4ac3-4e16-b7b4-51c512a07155

Male, 41.8 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the small intestine; primary biopsied or resected from the small intestine. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
